Somatic mutation profile of tumor specimen TCGA-A7-A0DB-01C (aliquot TCGA-A7-A0DB-01C-02D-A272-09) from TCGA case TCGA-A7-A0DB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.3 years (20,570 days).
Specimen TCGA-A7-A0DB-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6810404-b1aa-4669-b91a-d720e93635ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0DB-10A (Blood Derived Normal), aliquot TCGA-A7-A0DB-10A-02D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e7b34fb-a86b-40dc-b349-650301e66e1c

The open-access MAF lists 77 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 57, Silent 16, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ATG9B | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV52510448; called by mutect2, varscan2
- CACNA2D3 | c.675G>T p.P225= | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as COSV55531666, COSV99870579; called by mutect2, varscan2
- CCKBR | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs749874540, COSV58100133; called by mutect2, varscan2
- CD163L1 | c.2926C>A p.L976M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.591); catalogued as COSV58010744, COSV58023412; called by muse, mutect2, varscan2
- CEACAM20 | c.1740G>C p.E580D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.113); catalogued as COSV57603084; called by muse, varscan2
- EPHX2 | c.559G>T p.G187W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66845856; called by mutect2, varscan2
- FUS | c.1405G>T p.G469W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV54218768; called by muse, varscan2
- GLB1L2 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60279630; called by muse, mutect2, varscan2
- GOLGA6L9 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1189513616; called by mutect2, varscan2
- HEATR1 | c.6345A>C p.E2115D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59382639; called by muse, mutect2, varscan2
- HERC2 | c.5162C>A p.P1721Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV55345122; called by muse, mutect2, varscan2
- OBSL1 | c.2161C>A p.Q721K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs768834976; called by mutect2, varscan2
- OSBPL8 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as COSV53885145; called by muse, mutect2
- PEDS1-UBE2V1 | c.910T>G p.F304V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.135); catalogued as rs761220005, COSV59015503; called by muse, varscan2
- SLC9A2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV52136935; called by muse, mutect2, varscan2
- SYNE2 | c.12647C>G p.S4216C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.41); catalogued as COSV59967077; called by muse, mutect2, varscan2
- VANGL1 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as CM093990, COSV59621841, COSV59622631; called by mutect2, varscan2
- WNT5B | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60198884; called by muse, mutect2, varscan2
- ZNF454 | c.373del p.L125Cfs*35 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | catalogued as COSV104410823; called by pindel, varscan2
- ZNF506 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71354659; called by muse, mutect2, varscan2
- ABI3BP | c.2726C>A p.P909Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by mutect2, varscan2
- ALG5 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ANKIB1 | c.2602G>T p.G868W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by mutect2, varscan2
- ATP9B | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); called by mutect2, varscan2
- AXIN1 | c.2092C>A p.H698N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); called by mutect2, varscan2
- BCL9L | c.2680C>A p.P894T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); called by mutect2, varscan2
- BDH1 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by mutect2, varscan2
- BNIPL | c.295G>T p.G99W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by mutect2, varscan2
- CSHL1 | c.371T>C p.L124P (on ENST00000309894 / NM_022581.3; = p.L30P on NM_001318.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DTX3 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, varscan2
- ENO1 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HSPG2 | c.4907A>G p.Y1636C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- IL27RA | c.1741G>T p.G581W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by mutect2, varscan2
- IQSEC1 | c.2089C>A p.R697S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by mutect2, varscan2
- KLHL5 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.357); called by mutect2, varscan2
- LIG3 | c.2392G>C p.D798H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- LMBRD1 | c.1366C>A p.Q456K (on ENST00000649011; = p.Q434K on NM_018368.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by mutect2, varscan2
- LMNB1 | c.1562G>T p.W521L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by mutect2, varscan2
- MAP3K1 | c.2012_2013dup p.E672Rfs*14 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- MARK1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MCM3AP | c.4687C>A p.H1563N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); called by mutect2, varscan2
- MUC16 | c.39979C>A p.L13327I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.87); called by mutect2, varscan2
- NPHP3 | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PDK2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by mutect2, varscan2
- PFDN4 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PFKFB2 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | PolyPhen benign (0.109); called by mutect2, varscan2
- PLXNA1 | c.2369G>T p.W790L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.027); called by mutect2, varscan2
- SBF2 | c.2084C>A p.P695Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.027); called by mutect2, varscan2
- SCAMP2 | c.89C>A p.P30Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by mutect2, varscan2
- SLC24A1 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC6A12 | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SLC7A14 | c.2216C>A p.A739E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- SMC5 | c.3070-1G>T p.X1024_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- TCEAL5 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TEP1 | c.7258C>A p.H2420N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by mutect2, varscan2
- TEP1 | c.1186C>A p.R396S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by mutect2, varscan2
- TEX264 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); called by mutect2, varscan2
- TFAM | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- TFDP2 | c.1334C>A p.P445Q (on ENST00000489671 / NM_001178139.2; = p.P385Q on NM_006286.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- TMEM62 | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by mutect2, varscan2
- ALG11 | c.324C>T p.N108= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs759862905, COSV101584380; called by mutect2, varscan2
- CPAMD8 | c.652C>A p.R218= (on ENST00000651564; = p.R171= on NM_015692.5) | Silent (SNP) | VAF 4/29 reads (14%) | called by mutect2, varscan2
- CPXM1 | c.1671C>A p.S557= | Silent (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- FKBP8 | c.261C>A p.A87= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- GNPDA2 | c.681C>A p.S227= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs368664443; called by mutect2, varscan2
- H2AC12 | c.360G>A p.K120= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs766851091, COSV63617147; called by muse, mutect2, varscan2
- MACF1 | c.19980G>T p.S6660= (on ENST00000372915; = p.S4705= on NM_012090.5) | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- NGEF | c.24T>C p.D8= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV50948845; called by muse, mutect2, varscan2
- NUDT11 | c.345G>A p.R115= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV65665447; called by muse, mutect2, varscan2
- NUDT6 | c.906T>C p.H302= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV52652584; called by muse, mutect2, varscan2
- OVCH2 | c.1533C>A p.P511= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- PIH1D1 | c.651C>A p.P217= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99221138; called by muse, varscan2
- RYR3 | c.8043G>T p.V2681= (on ENST00000389232; = p.V2682= on NM_001036.6) | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- SYNPO2 | c.1407G>T p.V469= | Silent (SNP) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- TAGAP | c.498C>A p.P166= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- TLE6 | c.1596G>T p.A532= (on ENST00000246112 / NM_001143986.2; = p.A409= on NM_024760.3) | Silent (SNP) | VAF 5/29 reads (17%) | called by mutect2, varscan2
